Somatic mutation profile of tumor specimen BA2511D (aliquot aq-BA2511D) from BEATAML1.0 case 2567, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with inv(3)(q21q26.2) or t(3;3)(q21;q26.2), RPN1-EVI1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.8 years (26,242 days).
Specimen BA2511D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4444bd9-b286-4d25-ab6f-c0242e0f8431.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2700D (Solid Tissue Normal), aliquot aq-BA2700D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/378c3734-2e46-4f66-bcee-7d43519db370

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NALCN | c.3347G>T p.G1116V | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99216625; called by muse, mutect2, varscan2
- TRO | c.4062C>A p.S1354R | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- FRMPD1 | c.2517G>A p.R839= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV66698942, COSV66701116; called by muse, mutect2, varscan2
- GVINP1 | n.3867G>A | RNA (SNP) | VAF 15/248 reads (6%) | called by muse, mutect2
